Gene-level copy-number profile of tumor specimen TCGA-L9-A8F4-01A from TCGA case TCGA-L9-A8F4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.7 years (23,617 days).
Specimen TCGA-L9-A8F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bc96bf8f-7c03-4c4d-97dd-33bceb41e565.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L9-A8F4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3452c13-8d01-45ea-9793-f8302406914b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,845; copy number 2: 29,161; copy number 3: 20,384; copy number 4: 1,949; copy number 5: 2,037; copy number 6: 547; copy number 7: 427; copy number 8: 195; copy number 9: 11; copy number 10: 225; copy number 14: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L9-A8F4-01A-11D-A396-01): tumor purity 0.32, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,473 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,770,001–7,741,533, 1 gene, copy number 7 (within-gene range 4–7): GRM7.
- chr3:6,892,632–18,445,588, 224 genes, copy number 7–9 (broad region; genes not listed).
- chr3:115,802,363–117,139,389, 1 gene, copy number 5 (within-gene range 3–5): LSAMP.
- chr3:116,360,024–198,222,513, 1,489 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–7,851,151, 154 genes, copy number 5 (broad region; genes not listed).
- chr5:7,859,159–7,869,037, 1 gene, copy number 5: FASTKD3.
- chr5:10,971,836–11,904,446, 1 gene, copy number 7 (within-gene range 3–7): CTNND2.
- chr5:12,297,399–20,575,873, 112 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:21,196,720–21,779,522, 7 genes, copy number 6: AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–21,884,310, 1 gene, copy number 6: HSPD1P1.
- chr5:24,910,594–29,983,114, 49 genes, copy number 5: Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr5:36,588,506–38,671,216, 41 genes, copy number 6 (within-gene range 4–6): AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650.
- chr5:105,922,994–107,727,117, 9 genes, copy number 5–7: RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1.
- chr5:107,859,035–113,776,837, 75 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:60,046,755–63,693,249, 53 genes, copy number 6 (within-gene range 3–6): AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2.
- chr8:63,703,077–63,813,937, 2 genes, copy number 6: AC069133.1, LINC01289.
- chr8:79,259,402–83,100,846, 77 genes, copy number 10 (broad region; genes not listed).
- chr8:85,833,377–88,887,573, 37 genes, copy number 8–10: AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3.
- chr8:113,950,886–113,950,998, 1 gene, copy number 8: Y_RNA.
- chr8:114,791,653–118,951,885, 28 genes, copy number 5–7: CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B.
- chr8:120,052,180–137,092,183, 235 genes, copy number 6–14 (within-gene range 3–14) (broad region; genes not listed).
- chr8:140,940,562–141,060,596, 2 genes, copy number 6: RNA5SP278, AC100860.1.
- chr8:141,124,717–141,130,064, 1 gene, copy number 6: AC040970.1.
- chr10:6,682,513–7,411,486, 11 genes, copy number 7 (within-gene range 2–7): AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17.
- chr19:53,519,527–58,605,223, 423 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr22:18,733,914–25,350,322, 438 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
